Somatic mutation profile of tumor specimen TCGA-KP-A3VZ-01A (aliquot TCGA-KP-A3VZ-01A-11D-A228-09) from TCGA case TCGA-KP-A3VZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.4 years (25,366 days).
Specimen TCGA-KP-A3VZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c36fb18-7b75-4351-a5d3-ba42246c9993.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KP-A3VZ-10A (Blood Derived Normal), aliquot TCGA-KP-A3VZ-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/322fe72f-fb83-405a-a726-a84fa9ee8eb0

The open-access MAF lists 102 somatic variants for this specimen: 69 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 31, Frame Shift Del 4, Splice Site 4, Nonsense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 28/30 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAA1 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100086012; called by muse, mutect2, varscan2
- ADAMTS9 | c.3982G>A p.G1328S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as rs752972692, COSV99899203; called by muse, mutect2, varscan2
- ADGRF1 | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs529990841, COSV100982589; called by muse, mutect2, varscan2
- ADGRL3 | c.1950C>G p.H650Q (on ENST00000506720 / NM_001322402.2; = p.H582Q on NM_015236.6) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV100800338; called by muse, mutect2, varscan2
- ADNP2 | c.209C>A p.T70K | Missense Mutation (SNP) | VAF 19/19 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV100080730; called by muse, mutect2, varscan2
- ALMS1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs867586310, COSV52505548; called by muse, mutect2, varscan2
- ALOX15B | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0.268); catalogued as COSV101205597; called by muse, mutect2, varscan2
- ANKRD6 | c.1383G>C p.L461F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100329718; called by muse, mutect2, varscan2
- ARAF | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV99283123; called by muse, mutect2, varscan2
- ASTN2 | c.2702G>A p.G901D (on ENST00000313400 / NM_001365069.1; = p.G850D on NM_014010.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100526393; called by muse, mutect2, varscan2
- AXIN1 | c.395C>G p.S132W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs202238031, COSV99249628; called by muse, mutect2, varscan2
- BCAS1 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV101006139; called by muse, mutect2, varscan2
- BMX | c.1147+1G>A p.X383_splice | Splice Site (SNP) | VAF 40/95 reads (42%) | catalogued as COSV100564411; called by muse, mutect2, varscan2
- CATSPER3 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs368860211; called by muse, mutect2, varscan2
- CCDC9B | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV101233502; called by muse, mutect2, varscan2
- CHRNA9 | c.458G>C p.S153T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs151270280, COSV59573881; called by muse, mutect2, varscan2
- CNTNAP2 | c.706A>T p.I236F | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV100665065; called by muse, mutect2, varscan2
- CNTNAP5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757108906, COSV70486167; called by muse, mutect2, varscan2
- COL20A1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as rs753715173, COSV58913905; called by muse, mutect2, varscan2
- CYP4F8 | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV100358085; called by muse, mutect2, varscan2
- EVC2 | c.1919T>A p.M640K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV100185666; called by muse, mutect2, varscan2
- FCN3 | c.312C>G p.S104R | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99585318; called by muse, mutect2, varscan2
- GATC | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99985018; called by muse, mutect2, varscan2
- GNB1L | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs769991918, COSV61548782; called by muse, mutect2, varscan2
- KCND1 | c.1929G>T p.K643N | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as rs781871178, COSV99331823; called by muse, mutect2, varscan2
- KCNU1 | c.2886G>C p.K962N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101299118; called by muse, mutect2, varscan2
- KERA | c.42A>G p.I14M | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57131617, COSV99899386; called by muse, mutect2, varscan2
- LAMB1 | c.2688A>C p.E896D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.168); catalogued as COSV99740455; called by muse, mutect2
- LAMC3 | c.3188A>T p.Y1063F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.131); catalogued as COSV100735947; called by muse, mutect2, varscan2
- MRPL4 | c.553-2A>G p.X185_splice | Splice Site (SNP) | VAF 17/120 reads (14%) | catalogued as COSV99459886; called by muse, mutect2, varscan2
- NISCH | c.4030G>T p.A1344S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100401533; called by muse, mutect2, varscan2
- NKTR | c.4256G>T p.R1419I | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99235561; called by muse, mutect2
- NSMCE4A | c.376C>T p.R126* | Nonsense Mutation (SNP) | VAF 32/47 reads (68%) | catalogued as rs903676710, COSV100940045; called by muse, mutect2, varscan2
- NUCB2 | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60376801; called by muse, mutect2, varscan2
- OR2AK2 | c.796C>G p.R266G | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV100823416; called by muse, mutect2, varscan2
- OR2H1 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV101009822; called by muse, mutect2, varscan2
- OR4C13 | c.906G>C p.R302S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV101634162, COSV73648869; called by muse, mutect2, varscan2
- OR4D11 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV57587473; called by muse, mutect2, varscan2
- PABPC1L | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV99407726; called by muse, mutect2, varscan2
- PDCD2L | c.798-1G>A p.X266_splice | Splice Site (SNP) | VAF 63/361 reads (17%) | catalogued as rs761518682, COSV99874965; called by muse, mutect2, varscan2
- PODN | c.255C>A p.S85R (on ENST00000395871; = p.S37R on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100439465, COSV57013055; called by muse, mutect2, varscan2
- PROKR1 | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.022); catalogued as rs1257379143, COSV100375427; called by muse, mutect2, varscan2
- PRRG3 | c.601C>A p.Q201K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV100948601; called by muse, mutect2, varscan2
- RAB27B | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs1482845008, COSV100024048; called by mutect2, varscan2
- RASGEF1A | c.198+1G>A p.X66_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100988656; called by muse, mutect2, varscan2
- RINT1 | c.1139T>G p.V380G | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99994335; called by muse, mutect2, varscan2
- SEC24B | c.2323G>T p.A775S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV99493256; called by muse, mutect2, varscan2
- SHCBP1L | c.902A>G p.Q301R | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.577); catalogued as COSV100840968; called by muse, mutect2, varscan2
- SLC22A3 | c.1445T>A p.I482N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99278661; called by muse, mutect2, varscan2
- SLC26A5 | c.268A>G p.T90A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100099049; called by muse, mutect2
- SMARCD1 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.749); catalogued as COSV101202954; called by muse, mutect2, varscan2
- SORCS1 | c.1375A>T p.R459* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV53880769, COSV99545241; called by muse, mutect2, varscan2
- SPRED3 | c.454C>G p.H152D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100634190; called by muse, mutect2
- SUMO1 | c.39G>T p.L13F | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.399); catalogued as COSV101108612; called by muse, mutect2
- SYNE1 | c.17442G>A p.M5814I (on ENST00000367255 / NM_182961.4; = p.M5743I on NM_033071.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99560005; called by muse, mutect2, varscan2
- TBK1 | c.1528A>G p.S510G | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100538117; called by muse, mutect2, varscan2
- TEX15 | c.2669A>T p.D890V (on ENST00000256246; = p.D1273V on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV99821153; called by muse, mutect2, varscan2
- TRPC4AP | c.1621A>C p.S541R | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99328199; called by muse, mutect2, varscan2
- TTC7B | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as rs779544238, COSV100127744, COSV60625263; called by muse, mutect2, varscan2
- UGT1A5 | c.250T>A p.W84R | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100530116; called by muse, mutect2
- UNK | c.14C>G p.P5R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.994); catalogued as COSV53144377, COSV99504824; called by muse, mutect2, varscan2
- XDH | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148603901; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF619 | c.1297G>C p.V433L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV100123148; called by muse, mutect2, varscan2
- ADAD1 | c.649_677del p.F217Ifs*5 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, pindel, varscan2
- C12orf50 | c.236del p.P79Lfs*2 | Frame Shift Del (DEL) | VAF 26/59 reads (44%) | called by mutect2, pindel, varscan2
- NACC2 | c.1437del p.D480Tfs*30 | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2*
- NACC2 | c.1436del p.L479Pfs*31 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | called by mutect2*, varscan2
- TMEM190 | c.227T>G p.V76G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2
- AHNAK | c.8442T>A p.P2814= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV99946829; called by muse, mutect2, varscan2
- AP5B1 | c.1695C>G p.A565= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100375984; called by muse, mutect2, varscan2
- ARHGAP36 | c.732A>G p.Q244= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV52271554; called by muse, mutect2, varscan2
- CACNA1G | c.3811C>A p.R1271= | Silent (SNP) | VAF 34/47 reads (72%) | catalogued as COSV100661637; called by muse, mutect2, varscan2
- CAMSAP3 | c.1314G>A p.P438= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs899151732, COSV50336130; called by muse, mutect2, varscan2
- CLDN18 | c.309C>T p.C103= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99480748; called by muse, mutect2, varscan2
- CRB1 | c.1851A>G p.P617= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100957803; called by muse, mutect2, varscan2
- CSMD2 | c.1797C>G p.G599= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99588653; called by muse, mutect2, varscan2
- DNASE2 | c.717C>T p.Y239= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs759430127, COSV99262697; called by muse, mutect2, varscan2
- DNHD1 | c.13626G>A p.P4542= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV99599855; called by muse, mutect2, varscan2
- DOCK4 | c.5580G>A p.S1860= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs747119054, COSV101447833; called by muse, mutect2, varscan2
- GMFG | c.129G>A p.V43= | Silent (SNP) | VAF 19/223 reads (9%) | catalogued as COSV99453302; called by muse, mutect2
- HECTD2 | c.975T>G p.T325= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99978418; called by muse, mutect2, varscan2
- HSD17B14 | c.315G>A p.Q105= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV99622732; called by muse, varscan2
- ING4 | c.702G>C p.R234= (on ENST00000396807 / NM_001127582.2; = p.R233= on NM_016162.4) | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV99975979, COSV99976060; called by muse, mutect2, varscan2
- KRT6C | c.1509C>A p.V503= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV99359932; called by muse, mutect2
- LRGUK | c.1137C>G p.P379= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99603991; called by muse, mutect2, varscan2
- NAPEPLD | c.426C>G p.L142= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100439775; called by muse, mutect2, varscan2
- NEB | c.15027C>T p.V5009= | Silent (SNP) | VAF 43/72 reads (60%) | catalogued as COSV99419727; called by muse, mutect2, varscan2
- PCLO | c.14052C>G p.T4684= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100430540, COSV61634409; called by muse, varscan2
- PCNT | c.8569C>T p.L2857= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs375869631; ClinVar: likely benign; called by muse, varscan2
- PIGZ | c.276G>A p.S92= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs776038473, COSV99433746; called by muse, mutect2, varscan2
- RBM46 | c.1326C>T p.Y442= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV99908026; called by muse, mutect2, varscan2
- RBPMS | c.360G>A p.L120= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV55122822; called by muse, mutect2, varscan2
- RHPN2 | c.240C>G p.V80= | Silent (SNP) | VAF 16/237 reads (7%) | catalogued as COSV99577362; called by muse, mutect2
- SCN2A | c.2352G>A p.T784= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs369101059, COSV51850051; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN9A | c.3384C>T p.S1128= (on ENST00000303354; = p.S1117= on NM_002977.3) | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100312289; called by muse, mutect2, varscan2
- SPSB3 | c.237C>A p.A79= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99236452; called by muse, mutect2, varscan2
- TECPR1 | c.2121C>T p.D707= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV101130406; called by muse, mutect2, varscan2
- TPTE | c.1647A>G p.G549= (on ENST00000618007 / NM_199261.4; = p.G531= on NM_199259.4) | Silent (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- UNC13D | c.1872C>T p.T624= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99256440; called by muse, mutect2, varscan2
- MBNL1 | c.1016-710T>G | Intron (SNP) | VAF 33/89 reads (37%) | catalogued as COSV99220107; called by muse, mutect2, varscan2
- PRMT8 | c.418-877C>G | Intron (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99713323; called by muse, mutect2, varscan2
